Surgical pathology report (de-identified scan), TCGA case TCGA-37-5819, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Cureline, specimen TCGA-37-5819-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement
1	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	Lung Cancer	[REDACTED]	[REDACTED]	[REDACTED]
	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	Lung Cancer	[REDACTED]	[REDACTED]	[REDACTED]

[page 2 of 4]
Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/per container	Unit
Lung, upper right	Primary	Tumor	Tissue	Frozen	cryomold	1	450	mg
Blood	n/a	normal	Blood	Frozen	tube	1	4	ml

[page 3 of 4]
Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation
Surgery	Adenocarcinoma	3	2	2	0	no	no	no
Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no

[page 4 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

Cellular Tumor %
70
n/a

Source: NCI Genomic Data Commons file 635a677b-b194-4345-8af4-83d77d6c8ed6 (TCGA-37-5819.8C9B5277-0CBF-4BA1-BDA0-2C84BDADC9BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).